Somatic mutation profile of tumor specimen ALCH-AFFM-TTP1-A (aliquot ALCH-AFFM-TTP1-A-1-0-D-A667-36) from ALCHEMIST case ALCH-AFFM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.5 years (22,110 days).
Specimen ALCH-AFFM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4a05308-4a02-4abb-9a32-4822aeb995e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFFM-NB1-A (Blood Derived Normal), aliquot ALCH-AFFM-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8783647-28c0-455a-8749-dd6464621473

The open-access MAF lists 528 somatic variants for this specimen: 361 protein-altering or splice-affecting, 99 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 318, Silent 99, Intron 34, Nonsense Mutation 22, RNA 12, 5'UTR 9, Frame Shift Del 8, 3'UTR 8, Splice Site 6, Splice Region 4, Frame Shift Ins 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.4395G>T p.M1465I | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV61261560; called by muse, mutect2, varscan2
- ADAMTS18 | c.2299G>C p.V767L | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as COSV51403516; called by muse, mutect2, varscan2
- ADGRB3 | c.1412G>T p.C471F | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763509415; called by muse, mutect2, varscan2
- ADRA2A | c.1168G>T p.V390L | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54529651; called by muse, varscan2
- ALDH7A1 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 203/355 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs796052259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBS7 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 120/349 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs750750883; called by muse, mutect2, varscan2
- C1QTNF7 | c.155C>G p.P52R | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV54854036; called by muse, mutect2, varscan2
- C5AR2 | c.164T>C p.M55T | Missense Mutation (SNP) | VAF 117/352 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV57255919; called by muse, mutect2, varscan2
- CAPN1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 229/510 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368843790; called by muse, varscan2
- CCDC88A | c.5371C>G p.R1791G (on ENST00000436346 / NM_001365480.1; = p.R1763G on NM_018084.5) | Missense Mutation (SNP) | VAF 54/485 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs767911397; called by muse, mutect2, varscan2
- CDC73 | c.1195C>G p.R399G | Missense Mutation (SNP) | VAF 54/439 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66467683; called by muse, mutect2, varscan2
- CEP162 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1330115223; called by muse, mutect2, varscan2
- CNTN1 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61641836; called by muse, mutect2, varscan2
- CNTNAP1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 153/451 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV99226145; called by muse, mutect2, varscan2
- COCH | c.407C>T p.S136L (on ENST00000216361 / NM_001347720.1; = p.S71L on NM_004086.3) | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781725849, COSV53551315; called by muse, mutect2, varscan2
- CXCR1 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 187/380 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775562593; called by muse, mutect2, varscan2
- CYP2A7 | c.1249C>A p.L417M | Missense Mutation (SNP) | VAF 129/360 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52500224; called by muse, mutect2, varscan2
- DCC | c.1807C>A p.R603S | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV59087112; called by mutect2, varscan2
- DCDC2C | c.194C>A p.T65K | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193432081; called by muse, mutect2, varscan2
- DCHS2 | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1342666903; called by muse, mutect2
- DCST2 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs781085737, COSV99792087; called by muse, mutect2
- DIDO1 | c.4217G>T p.R1406L | Missense Mutation (SNP) | VAF 135/435 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV56631939; called by muse, mutect2, varscan2
- DPH5 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1056891868; called by muse, mutect2, varscan2
- DUSP26 | c.225C>G p.D75E | Missense Mutation (SNP) | VAF 232/392 reads (59%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99823409; called by muse, mutect2, varscan2
- DYM | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV53983755; called by muse, mutect2, varscan2
- EGR2 | c.1180G>C p.G394R | Missense Mutation (SNP) | VAF 171/377 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54346659; called by muse, mutect2, varscan2
- F5 | c.4042C>A p.L1348I | Missense Mutation (SNP) | VAF 92/564 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs1485283798, COSV63124463; called by muse, varscan2
- FBN2 | c.2303-1G>C p.X768_splice | Splice Site (SNP) | VAF 117/210 reads (56%) | catalogued as COSV104390302; called by muse, mutect2, varscan2
- FCRL5 | c.804C>A p.S268R | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.127); catalogued as rs148506545, COSV62512500; called by muse, mutect2, varscan2
- FCRLA | c.385C>T p.P129S (on ENST00000367959; = p.P106S on NM_032738.4) | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs781581298; called by muse, mutect2, varscan2
- FNBP1 | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as rs758242445; called by muse, mutect2, varscan2
- FSCB | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV61218002; called by muse, mutect2, varscan2
- GML | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 166/386 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV55276339; called by muse, mutect2, varscan2
- GPR78 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs769666701, COSV101224053; called by muse, mutect2, varscan2
- GRIA1 | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV99600502; called by muse, mutect2, varscan2
- GRIN2A | c.1067A>G p.Q356R | Missense Mutation (SNP) | VAF 124/398 reads (31%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.957); catalogued as COSV58035684; called by muse, varscan2
- IGSF9B | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs753336790; called by muse, mutect2, varscan2
- IL1F10 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs142851873; called by muse, mutect2, varscan2
- IRX4 | c.665C>G p.A222G | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51473581; called by muse, mutect2, varscan2
- JHY | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 170/400 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV56218045; called by muse, mutect2, varscan2
- KCNC2 | c.1717del p.E573Kfs*6 | Frame Shift Del (DEL) | VAF 66/274 reads (24%) | catalogued as COSV54383000; called by mutect2, pindel, varscan2
- KIR2DL1 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99383117; called by muse, mutect2, varscan2
- L1TD1 | c.2212C>A p.L738I | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as rs112463438, COSV100776540; called by muse, mutect2, varscan2
- LINGO2 | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV104394085; called by muse, mutect2, varscan2
- LRTM2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747004809, COSV54565773; called by muse, mutect2, varscan2
- MBOAT2 | c.1034C>A p.T345K | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60007511; called by muse, mutect2, varscan2
- MORC2 | c.2405G>T p.R802L (on ENST00000397641 / NM_001303256.3; = p.R740L on NM_014941.3) | Missense Mutation (SNP) | VAF 116/316 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV53199859; called by muse, mutect2, varscan2
- MS4A4A | c.678C>A p.H226Q | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.474); catalogued as COSV59701659; called by muse, mutect2, varscan2
- MTF2 | c.84G>T p.L28F | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.418); catalogued as rs1343847574; called by muse, mutect2, varscan2
- MTOR | c.6892G>T p.D2298Y | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63878696; called by muse, mutect2, varscan2
- MUC16 | c.31393C>A p.H10465N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as rs1173674238; called by muse, varscan2
- MUC17 | c.9463C>T p.P3155S | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as COSV60305685; called by muse, varscan2
- MUC17 | c.13066G>T p.G4356C | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399543563, COSV100075840; called by muse, mutect2, varscan2
- MUC4 | c.14339G>A p.G4780D (on ENST00000463781 / NM_018406.7; = p.G544D on NM_004532.6) | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as rs1360873404; called by muse, varscan2
- MUC5B | c.12817C>A p.P4273T | Missense Mutation (SNP) | VAF 278/627 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV71596447; called by muse, mutect2, varscan2
- NAV3 | c.6722del p.R2241Hfs*10 (on ENST00000397909 / NM_001024383.2; = p.R2219Hfs*10 on NM_014903.6) | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as COSV57115621; called by mutect2, pindel, varscan2
- NEXMIF | c.968A>T p.D323V | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV50086281; called by muse, mutect2, varscan2
- NOLC1 | c.2050G>C p.G684R | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64181157; called by muse, mutect2, varscan2
- OR10S1 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 203/448 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.909); catalogued as rs756988059; called by muse, mutect2, varscan2
- OR2M3 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 66/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1385041505, COSV101513384; called by muse, mutect2, varscan2
- OR6K3 | c.626C>A p.S209Y (on ENST00000368146; = p.S193Y on NM_001005327.2) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.905); catalogued as COSV63745521; called by muse, mutect2, varscan2
- PCDH15 | c.3308A>G p.Y1103C | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1429273836; called by muse, mutect2, varscan2
- PCDHB5 | c.1678G>C p.V560L | Missense Mutation (SNP) | VAF 549/958 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV50653565; called by muse, mutect2, varscan2
- PCDHGA3 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.036); catalogued as rs761130659; called by muse, mutect2, varscan2
- PDYN | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 208/688 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1242938963; called by muse, mutect2, varscan2
- PDZRN4 | c.1795G>T p.E599* (on ENST00000402685 / NM_001164595.2; = p.E341* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 65/305 reads (21%) | catalogued as COSV54205093; called by muse, mutect2, varscan2
- PHACTR4 | c.1429G>C p.D477H (on ENST00000373839 / NM_001350159.2; = p.D487H on NM_023923.4) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65784299; called by muse, mutect2, varscan2
- PHKG1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs373657174; called by muse, mutect2, varscan2
- PKHD1 | c.3410C>G p.T1137R | Missense Mutation (SNP) | VAF 156/583 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as rs753409918, COSV61874047; called by muse, mutect2, varscan2
- PLXNA4 | c.3049A>G p.M1017V | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1035974331; called by muse, varscan2
- PPP1R42 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV61207822; called by muse, mutect2, varscan2
- PRODH2 | c.1085G>T p.R362M (on ENST00000301175; = p.R286M on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 152/422 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.749); catalogued as rs1365476418, COSV56562167; called by muse, mutect2, varscan2
- PRR23C | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 91/457 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV68826930; called by muse, mutect2, varscan2
- PSD | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs768396232; called by muse, mutect2, varscan2
- RAB3GAP1 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 114/395 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs771764402; called by muse, varscan2
- RBMY1A1 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV58215500; called by muse, mutect2
- RDH11 | c.862C>G p.H288D | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV53619827; called by muse, varscan2
- RTN1 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs752220474, COSV50750570; called by muse, mutect2, varscan2
- SERPINI2 | c.832A>G p.M278V | Missense Mutation (SNP) | VAF 65/479 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV52988567; called by muse, mutect2, varscan2
- SIGLEC8 | c.735C>A p.Y245* | Nonsense Mutation (SNP) | VAF 17/131 reads (13%) | catalogued as rs553170554, COSV58475304; called by muse, mutect2, varscan2
- SKIDA1 | c.2423G>T p.R808L | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71610447; called by muse, mutect2, varscan2
- SLC24A2 | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 24/514 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1262620628; called by muse, mutect2
- SLC44A5 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs567560165; called by muse, mutect2, varscan2
- SPTA1 | c.6472A>G p.M2158V | Missense Mutation (SNP) | VAF 46/510 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs750421173; called by muse, mutect2
- SRRM2 | c.5579C>T p.P1860L | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as rs763967336, COSV100071202; called by muse, mutect2, varscan2
- STEAP4 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 113/643 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as rs747558374; called by muse, mutect2, varscan2
- SYNE3 | c.2761C>T p.R921W | Missense Mutation (SNP) | VAF 155/736 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs746262942; called by muse, mutect2, varscan2
- TAL1 | c.74G>C p.S25T | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1557679642; called by muse, mutect2, varscan2
- TBX19 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 124/623 reads (20%) | catalogued as COSV63196534; called by mutect2, varscan2
- TECTA | c.3845G>T p.G1282V | Missense Mutation (SNP) | VAF 244/498 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as rs374614757, COSV99878317; called by muse, mutect2, varscan2
- TMEM132D | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV101242722, COSV101243166; called by muse, mutect2, varscan2
- TMEM205 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 237/430 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs753913306, COSV55793339; called by muse, mutect2, varscan2
- TMPRSS15 | c.1486A>C p.S496R | Missense Mutation (SNP) | VAF 110/239 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs1393915782; called by muse, mutect2, varscan2
- TOGARAM2 | c.2986C>T p.R996C | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs749796315; called by muse, mutect2, varscan2
- TOPAZ1 | c.3796A>T p.R1266W | Missense Mutation (SNP) | VAF 72/120 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554441; called by muse, mutect2, varscan2
- TP53 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 159/347 reads (46%) | catalogued as CM103214, COSV52683572; called by muse, mutect2, varscan2
- TRIM77 | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs1372772400; called by muse, mutect2
- TRIO | c.2120A>T p.Q707L | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60088390; called by muse, mutect2, varscan2
- TSPAN32 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 55/347 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs777126996; called by muse, mutect2, varscan2
- TTN | c.45760G>T p.G15254C (on ENST00000591111; = p.G7830C on NM_003319.4) | Missense Mutation (SNP) | VAF 166/445 reads (37%) | PolyPhen probably damaging (1); catalogued as COSV60403581; called by muse, mutect2, varscan2
- TUBA3C | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 121/225 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as COSV67138970; called by muse, mutect2, varscan2
- USP24 | c.7678A>G p.I2560V | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1029373258; called by muse, mutect2, varscan2
- USP34 | c.6775G>C p.E2259Q | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV101277291; called by muse, mutect2
- ZC3H3 | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 150/329 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99368601; called by muse, mutect2, varscan2
- ZFHX4 | c.8515C>T p.P2839S | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.431); catalogued as rs1466141985; called by muse, mutect2, varscan2
- ZIM3 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 47/288 reads (16%) | catalogued as COSV54144975; called by muse, mutect2, varscan2
- ZNF208 | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.94); catalogued as COSV68109386; called by muse, mutect2, varscan2
- ZNF208 | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 98/265 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as rs753121364; called by muse, mutect2, varscan2
- ZNF574 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs556972498, COSV55902398; called by muse, mutect2, varscan2
- ZNF804B | c.3335del p.G1112Efs*3 | Frame Shift Del (DEL) | VAF 84/210 reads (40%) | catalogued as COSV60820220; called by mutect2, pindel, varscan2
- ABCA1 | c.3359A>T p.N1120I | Missense Mutation (SNP) | VAF 166/358 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ABCA5 | c.1785G>T p.V595= | Splice Region (SNP) | VAF 44/166 reads (27%) | called by muse, varscan2
- ABCC2 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 157/451 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- AC109583.1 | c.695A>G p.Y232C | Missense Mutation (SNP) | VAF 136/275 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ADAM12 | c.1112T>C p.M371T | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM12 | c.738T>A p.N246K | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS9 | c.2884T>A p.C962S | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRG1 | c.127A>G p.R43G | Missense Mutation (SNP) | VAF 163/822 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AFTPH | c.2525G>T p.S842I | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- ALS2 | c.3975G>T p.L1325F | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- AMD1 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 159/457 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ANKS1B | c.2034C>A p.S678R | Missense Mutation (SNP) | VAF 83/322 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANO1 | c.618G>T p.Q206H | Missense Mutation (SNP) | VAF 54/382 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- AOX1 | c.2671C>G p.L891V | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2
- APOBR | c.359C>A p.A120D | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ARRB1 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ART3 | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASB2 | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 229/1103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ASZ1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 105/356 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP1A3 | c.1748C>T p.T583M (on ENST00000545399 / NM_001256214.2; = p.T570M on NM_152296.5) | Missense Mutation (SNP) | VAF 190/578 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ATP1A4 | c.701G>T p.S234I | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATP8A2 | c.2377T>A p.C793S | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- ATP8B3 | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 72/125 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- BMPR2 | c.2524A>G p.R842G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD7 | c.1588C>A p.P530T | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- C12orf54 | c.136G>C p.V46L | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- C2orf69 | c.209A>T p.E70V | Missense Mutation (SNP) | VAF 111/280 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- C3orf33 | c.359G>C p.G120A (on ENST00000340171 / NM_001308229.2; = p.G77A on NM_173657.2) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACHD1 | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CALCRL | c.408+1G>T p.X136_splice | Splice Site (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- CAMTA2 | c.1769A>G p.H590R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- CATSPERE | c.2118A>T p.K706N | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC150 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- CDH17 | c.825C>A p.D275E | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP95 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 199/461 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CFAP91 | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CGB7 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 95/571 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CHAT | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 87/697 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CITED2 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 52/823 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CLCNKA | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- CLCNKB | c.1375A>T p.N459Y | Missense Mutation (SNP) | VAF 205/595 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CNST | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CNTLN | c.1467C>G p.N489K | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CNTN4 | c.2498T>A p.I833K | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- CNTN4 | c.2500C>T p.Q834* | Nonsense Mutation (SNP) | VAF 118/284 reads (42%) | called by muse, mutect2
- CNTNAP5 | c.1354T>A p.S452T | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- COL24A1 | c.2877+1G>T p.X959_splice | Splice Site (SNP) | VAF 37/205 reads (18%) | called by muse, mutect2, varscan2
- COPB1 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CPEB3 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- CPNE1 | c.1183A>G p.I395V (on ENST00000352393; = p.I400V on NM_003915.5) | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CRACD | c.1609T>C p.Y537H | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRISP3 | c.238C>A p.L80M (on ENST00000371159 / NM_001368123.1; = p.L62M on NM_006061.4) | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSF2RA | c.406T>A p.C136S | Missense Mutation (SNP) | VAF 131/403 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.7985A>C p.Y2662S (on ENST00000297405 / NM_001363185.1; = p.Y2558S on NM_052900.3) | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CTSC | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 56/838 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2
- CYP2B6 | c.1387G>C p.V463L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYSLTR1 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 108/170 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACT1 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCC | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DDR1 | c.2320G>T p.V774F (on ENST00000324771; = p.V737F on NM_001954.4) | Missense Mutation (SNP) | VAF 129/505 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHTKD1 | c.163G>C p.G55R | Missense Mutation (SNP) | VAF 187/360 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DHX30 | c.-27G>T | Splice Region (SNP) | VAF 78/144 reads (54%) | called by muse, mutect2, varscan2
- DNAH7 | c.10207A>T p.N3403Y | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, varscan2
- DSG1 | c.2389C>G p.P797A | Missense Mutation (SNP) | VAF 211/556 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DTWD2 | c.285G>T p.L95F | Missense Mutation (SNP) | VAF 162/296 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DYNC1H1 | c.4392G>C p.K1464N | Missense Mutation (SNP) | VAF 146/854 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DYNC1H1 | c.9259A>C p.N3087H | Missense Mutation (SNP) | VAF 74/992 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYSF | c.5117G>C p.C1706S | Missense Mutation (SNP) | VAF 46/632 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.171); called by muse, mutect2
- EDA2R | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 85/146 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EGLN3 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 62/205 reads (30%) | called by muse, mutect2, varscan2
- ELFN2 | c.2060del p.G687Afs*13 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- EP400 | c.7005T>G p.S2335R | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- FBN1 | c.4028C>A p.A1343E | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- FBN2 | c.8172del p.Y2725Ifs*70 | Frame Shift Del (DEL) | VAF 145/321 reads (45%) | called by mutect2, pindel, varscan2
- FGD2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 97/436 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF2 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FREM3 | c.1963C>A p.L655I | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2
- FSIP2 | c.12694C>A p.Q4232K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GCM2 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 170/531 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GFRA4 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- GLOD4 | c.509G>A p.W170* (on ENST00000301328 / NM_001366247.1; = p.W155* on NM_016080.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 59/121 reads (49%) | called by muse, mutect2, varscan2
- GOT2 | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPC5 | c.467A>T p.D156V | Missense Mutation (SNP) | VAF 153/474 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2
- GPRC6A | c.800T>C p.L267S | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.009); called by muse, mutect2
- GRB14 | c.725A>T p.H242L | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- HAO1 | c.50C>A p.S17* | Nonsense Mutation (SNP) | VAF 68/234 reads (29%) | called by muse, varscan2
- HEPACAM | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 104/790 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXB1 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- HYDIN | c.3017T>C p.L1006P | Missense Mutation (SNP) | VAF 116/382 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYDIN | c.2506C>A p.P836T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by mutect2, varscan2
- IFI27 | c.122-2A>T p.X41_splice | Splice Site (SNP) | VAF 194/375 reads (52%) | called by muse, mutect2, varscan2
- IGHG3 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 32/776 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- IGLV3-32 | c.120C>G p.C40W | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INPP4B | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- IRX4 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGA2B | c.2290A>T p.S764C | Missense Mutation (SNP) | VAF 318/767 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH2 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KALRN | c.8476G>A p.E2826K (on ENST00000360013 / NM_001024660.4; = p.E1129K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- KANK3 | c.702C>G p.D234E | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.89); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KAT2A | c.2136A>T p.R712= | Splice Region (SNP) | VAF 106/545 reads (19%) | called by muse, mutect2, varscan2
- KCNN2 | c.146del p.P49Rfs*120 (on ENST00000264773; = p.P261Rfs*120 on NM_021614.4) | Frame Shift Del (DEL) | VAF 232/436 reads (53%) | called by mutect2, pindel, varscan2
- KCNQ2 | c.1507T>C p.S503P (on ENST00000359125 / NM_172107.4; = p.S475P on NM_004518.6) | Missense Mutation (SNP) | VAF 132/481 reads (27%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIAA2026 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 103/152 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- KIF21B | c.3122C>G p.S1041C | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIF7 | c.364A>T p.R122W | Missense Mutation (SNP) | VAF 36/357 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR3DL1 | c.873C>A p.Y291* | Nonsense Mutation (SNP) | VAF 91/502 reads (18%) | called by muse, mutect2, varscan2
- KLHL32 | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- KLHL33 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- KMT2D | c.14677A>T p.S4893C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.9820C>T p.Q3274* | Nonsense Mutation (SNP) | VAF 153/466 reads (33%) | called by muse, mutect2, varscan2
- LIMCH1 | c.3209G>A p.C1070Y | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LLGL1 | c.1037T>G p.V346G | Missense Mutation (SNP) | VAF 182/357 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LRRC4B | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 104/557 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC7 | c.424G>C p.V142L (on ENST00000651989 / NM_001370785.2; = p.V109L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2
- MACF1 | c.16702C>T p.Q5568* (on ENST00000372915; = p.Q3610* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 58/302 reads (19%) | called by muse, mutect2, varscan2
- MAP3K20 | c.779T>A p.L260Q | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCHF5 | c.446T>G p.I149S | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MARS2 | c.482A>T p.Y161F | Missense Mutation (SNP) | VAF 136/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCAM | c.522G>C p.W174C | Missense Mutation (SNP) | VAF 24/539 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MED1 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MORC1 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRGPRG | c.583A>G p.R195G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2
- MRPL58 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 67/861 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- MTG1 | c.988G>T p.A330S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MUC16 | c.35661C>A p.S11887R | Missense Mutation (SNP) | VAF 86/151 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MUC19 | c.914C>A p.A305D | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MYBL2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MYF6 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 115/338 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYLK | c.2262G>T p.W754C | Missense Mutation (SNP) | VAF 157/621 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO18B | c.6686C>T p.A2229V | Missense Mutation (SNP) | VAF 122/491 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- MYPN | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 123/697 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NALCN | c.4393A>T p.N1465Y | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2
- NDNF | c.187A>T p.R63W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- NEU3 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 98/492 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NFATC2 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLGN4X | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 180/415 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NLRP13 | c.3037C>A p.L1013M | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP8 | c.3050G>T p.C1017F | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NPAP1 | c.2498C>T p.T833I | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- NRF1 | c.466-1G>T p.X156_splice | Splice Site (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- ODF2 | c.1391T>C p.V464A (on ENST00000434106 / NM_153433.2; = p.V440A on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR10G3 | c.786G>T p.R262S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- OR10G4 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR10K2 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 133/352 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- OR2J2 | c.63G>T p.W21C | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OR4X1 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR7E24 | c.371T>A p.L124H | Missense Mutation (SNP) | VAF 129/253 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PAN3 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- PATJ | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCDHB16 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 241/538 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCNX2 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE3B | c.2825C>T p.A942V | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2
- PFDN2 | c.76-2A>T p.X26_splice | Splice Site (SNP) | VAF 34/180 reads (19%) | called by muse, mutect2, varscan2
- PHLDB2 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 59/427 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PKDCC | c.877G>C p.V293L | Missense Mutation (SNP) | VAF 98/922 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- PKHD1L1 | c.6037G>T p.G2013W | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCE1 | c.3082G>T p.V1028F | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- PLEKHG2 | c.3745G>C p.A1249P | Missense Mutation (SNP) | VAF 120/358 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- POC5 | c.500G>A p.S167N (on ENST00000428202 / NM_001099271.2; = p.S142N on NM_152408.2) | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- POF1B | c.1678C>A p.L560I | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLE | c.2195A>T p.K732M | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- POLE3 | c.439A>G p.N147D | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- POTEA | c.1207G>T p.E403* (on ENST00000519951 / NM_001005365.2; = p.E357* on NM_001002920.1) | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- PPIL3 | c.356del p.G119Efs*3 (on ENST00000392283 / NM_130906.3; = p.G123Efs*3 on NM_032472.4) | Frame Shift Del (DEL) | VAF 52/170 reads (31%) | called by mutect2, pindel, varscan2
- PPOX | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 238/569 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PRDM4 | c.1001A>G p.Q334R | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PRKX | c.1004C>A p.T335N | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRRT4 | c.2050G>T p.G684C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRSS58 | c.213dup p.A72Sfs*4 | Frame Shift Ins (INS) | VAF 40/147 reads (27%) | called by mutect2, pindel, varscan2
- PSME4 | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- PTBP3 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 206/393 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, varscan2
- PTPRC | c.2938T>C p.Y980H | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASAL2 | c.1807G>T p.G603W | Missense Mutation (SNP) | VAF 121/311 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- RGS11 | c.63+7G>A | Splice Region (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- RHAG | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 121/447 reads (27%) | called by muse, mutect2, varscan2
- RIMBP3 | c.3887A>G p.Q1296R | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RIMS1 | c.3800G>T p.R1267M | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RNF150 | c.1005G>T p.M335I | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- RNF2 | c.865A>T p.K289* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- ROBO3 | c.3719C>T p.P1240L | Missense Mutation (SNP) | VAF 47/394 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ROBO4 | c.1657dup p.R553Pfs*36 | Frame Shift Ins (INS) | VAF 140/379 reads (37%) | called by mutect2, pindel, varscan2
- RPS6KA6 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 45/87 reads (52%) | called by muse, mutect2, varscan2
- RTL9 | c.1698G>T p.Q566H | Missense Mutation (SNP) | VAF 93/149 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RTN3 | c.2296G>T p.A766S (on ENST00000377819 / NM_001265589.2; = p.A747S on NM_201428.3) | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.11174T>A p.L3725Q | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- S1PR3 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 193/428 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by mutect2, varscan2
- SAMD9L | c.4722A>T p.E1574D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, varscan2
- SASH1 | c.1389G>T p.K463N | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SASH1 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCARB2 | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- SDF2 | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 149/577 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SH2D5 | c.1199C>A p.P400Q (on ENST00000444387 / NM_001103161.2; = p.P316Q on NM_001103160.2) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, varscan2
- SH2D5 | c.1198C>A p.P400T (on ENST00000444387 / NM_001103161.2; = p.P316T on NM_001103160.2) | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, varscan2
- SHCBP1L | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SLC16A5 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 710/1051 reads (68%) | SIFT tolerated (0.47); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC17A1 | c.688A>T p.I230L | Missense Mutation (SNP) | VAF 81/329 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- SLC34A1 | c.1699G>C p.G567R | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A8 | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A3R1 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 188/261 reads (72%) | called by muse, mutect2, varscan2
- SLC9C1 | c.2159T>C p.L720P | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- SLCO2B1 | c.1432A>T p.S478C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SLCO6A1 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- SLITRK5 | c.491A>C p.Y164S | Missense Mutation (SNP) | VAF 22/337 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2
- SMC4 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 60/252 reads (24%) | called by muse, varscan2
- SNPH | c.1315A>T p.T439S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPICE1 | c.2210A>T p.Q737L | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SRFBP1 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 100/174 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SRGAP3 | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 126/234 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SRRM1 | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- STAB2 | c.6046G>T p.D2016Y | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- STARD7 | c.1015A>C p.K339Q | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- STK24 | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STRC | c.3853C>T p.Q1285* | Nonsense Mutation (SNP) | VAF 79/201 reads (39%) | called by muse, mutect2, varscan2
- STYK1 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 84/347 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUPT5H | c.2008A>T p.S670C | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SYT16 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- TAF4B | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TBX3 | c.554A>T p.Y185F | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TGOLN2 | c.137T>G p.L46W | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- THSD4 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 156/325 reads (48%) | called by muse, mutect2, varscan2
- TIAM2 | c.3397A>G p.T1133A | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TICRR | c.269T>G p.L90R | Missense Mutation (SNP) | VAF 186/271 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- TNIK | c.2087del p.G696Dfs*4 | Frame Shift Del (DEL) | VAF 50/198 reads (25%) | called by mutect2, pindel, varscan2
- TNN | c.3403G>T p.D1135Y | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TNS3 | c.1705A>G p.K569E | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2
- TPH2 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- TPM3 | c.814A>G p.S272G | Missense Mutation (SNP) | VAF 37/484 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- TRIM49 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by mutect2, varscan2
- TRPC6 | c.2686T>C p.Y896H | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- TSHZ1 | c.2979G>T p.L993F (on ENST00000580243 / NM_001308210.2; = p.L948F on NM_005786.6) | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPAN10 | c.749G>T p.C250F (on ENST00000574882 / NM_001290212.1; = p.C212F on NM_031945.4) | Missense Mutation (SNP) | VAF 383/829 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPAN11 | c.70A>G p.N24D | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TUBB8B | c.320C>G p.T107R | Missense Mutation (SNP) | VAF 203/971 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); called by muse, varscan2
- TYW1B | c.906A>T p.E302D | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UAP1L1 | c.628A>T p.K210* | Nonsense Mutation (SNP) | VAF 60/130 reads (46%) | called by muse, varscan2
- UBE3A | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 60/373 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13C | c.4019G>C p.G1340A | Missense Mutation (SNP) | VAF 124/247 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UROC1 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 110/366 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.8508T>A p.Y2836* | Nonsense Mutation (SNP) | VAF 104/245 reads (42%) | called by muse, mutect2, varscan2
- VPS13B | c.6312G>C p.K2104N | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- VPS51 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 115/230 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VSTM5 | c.53T>A p.L18H | Missense Mutation (SNP) | VAF 82/494 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- VSX1 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR25 | c.956C>A p.T319K | Missense Mutation (SNP) | VAF 156/301 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDR72 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 176/336 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, varscan2
- WFIKKN2 | c.1661T>G p.V554G | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- XIRP2 | c.8239C>G p.Q2747E (on ENST00000628543; = p.Q2922E on NM_152381.6) | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZFPM2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF479 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF729 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF846 | c.263dup p.L89Tfs*27 | Frame Shift Ins (INS) | VAF 113/260 reads (43%) | called by mutect2, pindel, varscan2
- ADAM2 | c.9C>A p.R3= | Silent (SNP) | VAF 282/477 reads (59%) | catalogued as rs549926110, COSV55866557; called by muse, mutect2, varscan2
- ADD2 | c.1749A>G p.K583= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- ADGRD1 | c.2481G>T p.T827= | Silent (SNP) | VAF 149/493 reads (30%) | catalogued as COSV55445014; called by muse, mutect2, varscan2
- ADGRG2 | c.1632C>T p.T544= (on ENST00000379869 / NM_001079858.3; = p.T541= on NM_005756.4) | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- APH1A | c.333C>T p.P111= | Silent (SNP) | VAF 89/219 reads (41%) | called by muse, mutect2, varscan2
- ARFIP1 | c.189A>T p.A63= | Silent (SNP) | VAF 33/202 reads (16%) | called by muse, mutect2, varscan2
- ATP13A4 | c.1881A>G p.P627= | Silent (SNP) | VAF 40/189 reads (21%) | called by muse, mutect2, varscan2
- BFSP2 | c.267G>T p.R89= | Silent (SNP) | VAF 128/479 reads (27%) | catalogued as COSV56589351; called by muse, mutect2, varscan2
- BPIFB6 | c.1011C>A p.T337= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as COSV100848556; called by muse, mutect2, varscan2
- C20orf202 | c.321G>T p.L107= | Silent (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- CASP5 | c.603A>G p.T201= | Silent (SNP) | VAF 159/330 reads (48%) | catalogued as rs1278722154; called by muse, mutect2, varscan2
- CNR1 | c.612G>T p.V204= | Silent (SNP) | VAF 152/400 reads (38%) | catalogued as COSV62992813; called by muse, mutect2, varscan2
- COL9A2 | c.1380C>T p.G460= | Silent (SNP) | VAF 80/407 reads (20%) | catalogued as rs747251984; called by muse, mutect2, varscan2
- CRACR2A | c.1383G>T p.G461= | Silent (SNP) | VAF 138/420 reads (33%) | called by muse, varscan2
- CRB2 | c.2292A>T p.R764= | Silent (SNP) | VAF 112/195 reads (57%) | called by muse, mutect2, varscan2
- CSMD1 | c.1605C>A p.A535= (on ENST00000520002; = p.A534= on NM_033225.6) | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- CSMD3 | c.3249C>T p.Y1083= (on ENST00000297405 / NM_001363185.1; = p.Y979= on NM_052900.3) | Silent (SNP) | VAF 157/378 reads (42%) | catalogued as COSV52324717; called by muse, mutect2, varscan2
- CSPG5 | c.1629G>T p.S543= (on ENST00000383738 / NM_001206943.2; = p.S516= on NM_006574.4) | Silent (SNP) | VAF 91/181 reads (50%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.1932C>T p.P644= | Silent (SNP) | VAF 75/413 reads (18%) | catalogued as rs148428403, COSV50406576; called by muse, mutect2, varscan2
- CTTNBP2 | c.1515T>G p.G505= | Silent (SNP) | VAF 67/243 reads (28%) | called by muse, mutect2, varscan2
- DHX35 | c.955C>T p.L319= | Silent (SNP) | VAF 80/285 reads (28%) | catalogued as rs763893344; called by muse, mutect2, varscan2
- DNAH12 | c.8857T>C p.L2953= (on ENST00000351747; = p.L3821= on NM_001366028.2) | Silent (SNP) | VAF 124/288 reads (43%) | called by muse, mutect2, varscan2
- DNAH3 | c.4395G>T p.G1465= | Silent (SNP) | VAF 73/229 reads (32%) | catalogued as COSV99768131; called by muse, mutect2, varscan2
- DPP6 | c.2032C>A p.R678= (on ENST00000377770 / NM_001364500.2; = p.R616= on NM_001936.5) | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV59633054; called by muse, mutect2, varscan2
- ECE2 | c.69G>A p.R23= | Silent (SNP) | VAF 147/762 reads (19%) | catalogued as COSV100668769; called by muse, mutect2, varscan2
- FLNA | c.5241G>T p.S1747= (on ENST00000369850 / NM_001110556.2; = p.S1739= on NM_001456.3) | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV61045587; called by muse, mutect2, varscan2
- GRID1 | c.1893C>A p.R631= | Silent (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- H2BW2 | c.444G>C p.A148= | Silent (SNP) | VAF 93/174 reads (53%) | catalogued as COSV54581810; called by muse, varscan2
- IDO1 | c.1047C>A p.I349= | Silent (SNP) | VAF 257/512 reads (50%) | catalogued as COSV99503562; called by muse, mutect2, varscan2
- IGKV1-9 | c.81C>A p.T27= | Silent (SNP) | VAF 84/799 reads (11%) | catalogued as rs956992128; called by muse, mutect2, varscan2
- IGLV3-10 | c.57C>A p.A19= | Silent (SNP) | VAF 90/291 reads (31%) | called by muse, mutect2, varscan2
- ITGA8 | c.1425A>T p.T475= | Silent (SNP) | VAF 67/481 reads (14%) | called by muse, mutect2, varscan2
- KCND3 | c.1347C>A p.L449= | Silent (SNP) | VAF 217/624 reads (35%) | called by muse, mutect2, varscan2
- KCNT1 | c.3342G>T p.L1114= (on ENST00000488444; = p.L1140= on NM_020822.3) | Silent (SNP) | VAF 155/279 reads (56%) | called by muse, mutect2, varscan2
- KDR | c.2385G>T p.G795= | Silent (SNP) | VAF 41/378 reads (11%) | called by muse, mutect2, varscan2
- KLHL14 | c.333C>A p.P111= | Silent (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- LRRC14B | c.1380C>A p.A460= | Silent (SNP) | VAF 163/972 reads (17%) | called by muse, mutect2, varscan2
- LRRK2 | c.3657T>A p.S1219= | Silent (SNP) | VAF 89/236 reads (38%) | called by muse, mutect2, varscan2
- MAB21L1 | c.895C>A p.R299= | Silent (SNP) | VAF 115/220 reads (52%) | catalogued as COSV59788776, COSV59792977; called by muse, mutect2, varscan2
- MAGEE2 | c.1398A>T p.L466= | Silent (SNP) | VAF 60/102 reads (59%) | called by muse, mutect2, varscan2
- MAML3 | c.2034G>A p.V678= | Silent (SNP) | VAF 103/472 reads (22%) | called by muse, mutect2, varscan2
- MCM4 | c.2541G>T p.L847= | Silent (SNP) | VAF 30/263 reads (11%) | called by muse, mutect2, varscan2
- MOK | c.792A>C p.A264= | Silent (SNP) | VAF 63/455 reads (14%) | called by muse, mutect2, varscan2
- MROH1 | c.1320G>T p.A440= | Silent (SNP) | VAF 150/308 reads (49%) | catalogued as COSV58188051; called by muse, mutect2, varscan2
- MTF2 | c.738G>T p.T246= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as rs778891390; called by muse, varscan2
- MUC19 | c.915C>A p.A305= | Silent (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- MYLK3 | c.1332C>A p.G444= | Silent (SNP) | VAF 62/353 reads (18%) | called by muse, mutect2, varscan2
- MYO1A | c.1840C>T p.L614= | Silent (SNP) | VAF 98/684 reads (14%) | called by muse, mutect2, varscan2
- NME8 | c.111C>T p.A37= | Silent (SNP) | VAF 79/336 reads (24%) | called by muse, mutect2, varscan2
- NOL4 | c.891G>T p.L297= | Silent (SNP) | VAF 88/390 reads (23%) | called by muse, mutect2, varscan2
- NRAS | c.372A>T p.T124= | Silent (SNP) | VAF 140/374 reads (37%) | called by muse, varscan2
- NWD2 | c.381G>C p.G127= | Silent (SNP) | VAF 51/144 reads (35%) | called by muse, mutect2, varscan2
- NXPH1 | c.48C>A p.V16= | Silent (SNP) | VAF 130/438 reads (30%) | called by muse, mutect2, varscan2
- OR10A4 | c.162T>A p.S54= | Silent (SNP) | VAF 113/263 reads (43%) | catalogued as rs1430451125; called by muse, mutect2, varscan2
- OR2M2 | c.516G>T p.R172= | Silent (SNP) | VAF 63/334 reads (19%) | called by muse, mutect2, varscan2
- OR2M7 | c.93C>A p.V31= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- OR2T2 | c.195C>T p.S65= | Silent (SNP) | VAF 111/554 reads (20%) | catalogued as rs756442321, COSV100737578; called by muse, mutect2, varscan2
- OR4A47 | c.429G>T p.L143= | Silent (SNP) | VAF 35/208 reads (17%) | called by muse, mutect2, varscan2
- OR52E6 | c.198C>A p.A66= | Silent (SNP) | VAF 50/102 reads (49%) | called by mutect2, varscan2
- OTOF | c.5949C>A p.L1983= (on ENST00000272371 / NM_194248.3; = p.L1216= on NM_004802.4) | Silent (SNP) | VAF 305/570 reads (54%) | called by muse, mutect2, varscan2
- PCDH10 | c.114T>A p.A38= | Silent (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- PCDH10 | c.1468C>A p.R490= | Silent (SNP) | VAF 35/201 reads (17%) | catalogued as COSV52105405, COSV99992540; called by muse, mutect2, varscan2
- PCDH11X | c.3903A>C p.T1301= | Silent (SNP) | VAF 257/400 reads (64%) | called by muse, mutect2, varscan2
- PIP4K2A | c.759G>A p.K253= | Silent (SNP) | VAF 61/488 reads (13%) | catalogued as COSV60543284; called by muse, mutect2, varscan2
- PLXND1 | c.4680G>T p.V1560= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV60709141; called by muse, mutect2, varscan2
- PPARGC1A | c.2073A>G p.T691= | Silent (SNP) | VAF 24/326 reads (7%) | catalogued as rs1356010564; called by muse, mutect2
- PRAMEF1 | c.316C>A p.R106= | Silent (SNP) | VAF 77/263 reads (29%) | catalogued as rs529027078; called by muse, mutect2, varscan2
- PROKR1 | c.894G>A p.A298= | Silent (SNP) | VAF 335/566 reads (59%) | catalogued as COSV58136981; called by muse, mutect2, varscan2
- PRSS38 | c.462G>T p.V154= | Silent (SNP) | VAF 180/475 reads (38%) | called by muse, mutect2, varscan2
- RAB18 | c.16C>T p.L6= | Silent (SNP) | VAF 34/922 reads (4%) | called by muse, mutect2
- RASL10A | c.294G>A p.P98= | Silent (SNP) | VAF 72/396 reads (18%) | catalogued as rs369427009; called by muse, mutect2, varscan2
- RIMS2 | c.3012A>G p.L1004= (on ENST00000666250 / NM_001348490.2; = p.L812= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 40/276 reads (14%) | catalogued as COSV99153307; called by muse, varscan2
- SALL3 | c.3534G>T p.V1178= | Silent (SNP) | VAF 34/156 reads (22%) | called by muse, varscan2
- SCD | c.573A>T p.P191= | Silent (SNP) | VAF 144/350 reads (41%) | catalogued as rs372962648; called by muse, mutect2, varscan2
- SH2D5 | c.1200A>C p.P400= (on ENST00000444387 / NM_001103161.2; = p.P316= on NM_001103160.2) | Silent (SNP) | VAF 46/161 reads (29%) | catalogued as rs1183729493; called by muse, varscan2
- SLC50A1 | c.244C>T p.L82= | Silent (SNP) | VAF 16/278 reads (6%) | called by muse, mutect2
- SRD5A3 | c.342T>A p.I114= | Silent (SNP) | VAF 11/233 reads (5%) | called by muse, mutect2
- SREBF2 | c.1935G>T p.R645= | Silent (SNP) | VAF 92/439 reads (21%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.36G>T p.A12= | Silent (SNP) | VAF 260/531 reads (49%) | called by muse, mutect2, varscan2
- STAM2 | c.1398T>A p.S466= | Silent (SNP) | VAF 32/378 reads (8%) | called by muse, mutect2
- TEX37 | c.114G>A p.P38= | Silent (SNP) | VAF 40/442 reads (9%) | catalogued as rs772549037, COSV57556158; called by muse, mutect2
- TFAP2C | c.456C>T p.H152= | Silent (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- TGM5 | c.1986C>A p.L662= (on ENST00000220420 / NM_201631.4; = p.L580= on NM_004245.4) | Silent (SNP) | VAF 43/425 reads (10%) | called by muse, mutect2
- TLN2 | c.6438G>T p.A2146= | Silent (SNP) | VAF 116/215 reads (54%) | catalogued as rs769514789, COSV60890747; called by muse, mutect2, varscan2
- TM2D3 | c.450T>G p.P150= (on ENST00000333202 / NM_078474.3; = p.P124= on NM_025141.3) | Silent (SNP) | VAF 102/619 reads (16%) | called by muse, mutect2, varscan2
- TNN | c.3402G>T p.G1134= | Silent (SNP) | VAF 36/267 reads (13%) | called by muse, mutect2, varscan2
- TPH2 | c.204C>T p.F68= | Silent (SNP) | VAF 94/324 reads (29%) | catalogued as rs1393293419; called by muse, mutect2
- TRBV27 | c.344C>A p.*115= | Silent (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.15135C>A p.P5045= (on ENST00000591111; = p.P4118= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.9666A>T p.A3222= (on ENST00000591111; = p.A3176= on NM_003319.4) | Silent (SNP) | VAF 107/323 reads (33%) | called by muse, mutect2, varscan2
- UBE3D | c.906C>T p.I302= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as COSV52757063; called by muse, mutect2, varscan2
- VIL1 | c.1071C>A p.G357= | Silent (SNP) | VAF 100/233 reads (43%) | called by muse, mutect2, varscan2
- YAF2 | c.54G>T p.S18= | Silent (SNP) | VAF 183/488 reads (38%) | called by muse, mutect2, varscan2
- ZBTB16 | c.1152G>T p.L384= | Silent (SNP) | VAF 34/218 reads (16%) | called by muse, mutect2, varscan2
- ZFHX4 | c.2064G>T p.R688= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV51492146, COSV99257002; called by muse, mutect2, varscan2
- ZNF112 | c.1917T>C p.C639= (on ENST00000337401 / NM_001083335.2; = p.C633= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- ZNF350 | c.1317A>T p.A439= | Silent (SNP) | VAF 31/241 reads (13%) | called by muse, mutect2, varscan2
- ZNF570 | c.1590A>G p.P530= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs752457349; called by muse, mutect2, varscan2
- ZSCAN1 | c.978C>G p.G326= | Silent (SNP) | VAF 128/377 reads (34%) | called by muse, mutect2, varscan2
- AC064805.2 | n.1807G>T | RNA (SNP) | VAF 101/879 reads (11%) | catalogued as rs774116031; called by muse, mutect2, varscan2
- AC099654.5 | n.30A>G | RNA (SNP) | VAF 51/134 reads (38%) | called by muse, mutect2, varscan2
- ACADSB | c.1129-9T>A | Intron (SNP) | VAF 157/438 reads (36%) | called by muse, mutect2, varscan2
- AL590867.2 | n.290C>A | RNA (SNP) | VAF 230/627 reads (37%) | catalogued as rs768615333; called by muse, mutect2, varscan2
- ANKRD26P1 | n.282C>A | RNA (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- AP000755.1 | n.299C>G | RNA (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.870+86C>T | Intron (SNP) | VAF 53/195 reads (27%) | called by muse, mutect2, varscan2
- BATF2 | c.142-53G>T | Intron (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- BRCA1 | c.*1264G>C | 3'UTR (SNP) | VAF 164/511 reads (32%) | called by muse, mutect2, varscan2
- BRCA1 | c.*704G>A | 3'UTR (SNP) | VAF 11/88 reads (13%) | catalogued as rs1325204994; called by mutect2, varscan2
- BSND | c.-35del | 5'UTR (DEL) | VAF 62/181 reads (34%) | called by mutect2, pindel
- CACNB2 | c.120+291T>A | Intron (SNP) | VAF 71/524 reads (14%) | called by muse, mutect2, varscan2
- CFAP46 | c.7117+592G>T | Intron (SNP) | VAF 49/229 reads (21%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+312del | Intron (DEL) | VAF 212/655 reads (32%) | called by mutect2, pindel, varscan2
- COL11A1 | c.897+287G>T | Intron (SNP) | VAF 96/295 reads (33%) | catalogued as COSV62178843; called by muse, mutect2, varscan2
- CTDP1 | chr18:79679460 G>C | 5'Flank (SNP) | VAF 53/356 reads (15%) | called by muse, mutect2, varscan2
- CTNNB1 | c.1082-41T>C | Intron (SNP) | VAF 90/199 reads (45%) | called by muse, mutect2, varscan2
- DCTN5 | c.452-23G>A | Intron (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.615+5845A>G | Intron (SNP) | VAF 45/140 reads (32%) | called by muse, varscan2
- DOCK4 | c.3402-458T>C | Intron (SNP) | VAF 74/274 reads (27%) | catalogued as rs545614903; called by muse, varscan2
- ESPNP | chr1:16691276 G>T | 3'Flank (SNP) | VAF 42/372 reads (11%) | called by mutect2, varscan2
- FAM183BP | n.1004G>T | RNA (SNP) | VAF 99/440 reads (23%) | called by muse, mutect2, varscan2
- FAM90A27P | n.611C>T | RNA (SNP) | VAF 17/107 reads (16%) | catalogued as rs1021097158; called by muse, mutect2, varscan2
- FAM90A27P | n.1002A>G | RNA (SNP) | VAF 187/585 reads (32%) | called by muse, mutect2, varscan2
- GATA3 | chr10:8051044 G>T | 5'Flank (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- GC | c.-14C>A | 5'UTR (SNP) | VAF 57/182 reads (31%) | called by muse, mutect2, varscan2
- GFOD1 | c.*3979G>A | 3'UTR (SNP) | VAF 98/259 reads (38%) | called by muse, mutect2, varscan2
- GOT1L1 | c.116-39A>G | Intron (SNP) | VAF 138/241 reads (57%) | called by muse, mutect2, varscan2
- GP2 | c.94+41G>T | Intron (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- HMG20B | c.473-10C>G | Intron (SNP) | VAF 146/269 reads (54%) | called by muse, mutect2, varscan2
- ITGA2B | c.1394-111G>T | Intron (SNP) | VAF 239/765 reads (31%) | called by muse, mutect2, varscan2
- ITGA2B | c.847+28G>C | Intron (SNP) | VAF 82/842 reads (10%) | called by muse, mutect2
- KCNQ2 | c.1763+99G>T | Intron (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- LINC01565 | n.1132G>T | RNA (SNP) | VAF 46/159 reads (29%) | called by muse, varscan2
- LINC02868 | n.203C>T | RNA (SNP) | VAF 31/178 reads (17%) | catalogued as rs887349412; called by muse, mutect2, varscan2
- MMAB | c.*1416C>T | 3'UTR (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- MPV17 | c.71-9C>A | Intron (SNP) | VAF 64/846 reads (8%) | called by muse, mutect2
- NR5A2 | c.1110+8803G>C | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-68079C>T | Intron (SNP) | VAF 50/79 reads (63%) | called by muse, mutect2, varscan2
- PEG10 | c.*510G>A | 3'UTR (SNP) | VAF 73/237 reads (31%) | called by muse, mutect2, varscan2
- PHACTR1 | c.104-47C>A | Intron (SNP) | VAF 64/206 reads (31%) | catalogued as rs1357240403; called by muse, mutect2, varscan2
- PLEKHM3 | c.1886+990G>T | Intron (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- PON1 | c.-1C>T | 5'UTR (SNP) | VAF 226/642 reads (35%) | called by muse, mutect2, varscan2
- POTEC | c.1126+1500G>A | Intron (SNP) | VAF 44/266 reads (17%) | called by muse, mutect2, varscan2
- PTPRF | c.3974-842G>T | Intron (SNP) | VAF 84/557 reads (15%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792531 C>T | 3'Flank (SNP) | VAF 179/509 reads (35%) | called by muse, mutect2, varscan2
- ROBO3 | c.*6G>T | 3'UTR (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- RPGR | c.2520+830G>T | Intron (SNP) | VAF 51/92 reads (55%) | called by muse, varscan2
- SIRPD | c.422-3013C>T | Intron (SNP) | VAF 76/254 reads (30%) | called by muse, mutect2, varscan2
- SIVA1 | c.-41G>C | 5'UTR (SNP) | VAF 42/153 reads (27%) | called by muse, mutect2, varscan2
- SLC36A2 | c.*31C>A | 3'UTR (SNP) | VAF 146/270 reads (54%) | catalogued as COSV58862866; called by muse, mutect2, varscan2
- SNORD116-8 | n.91G>C | RNA (SNP) | VAF 122/326 reads (37%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.1836C>A | RNA (SNP) | VAF 75/173 reads (43%) | called by mutect2, varscan2
- SUV39H2 | c.850-264G>A | Intron (SNP) | VAF 32/208 reads (15%) | catalogued as rs911550454; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2095G>C | Intron (SNP) | VAF 41/357 reads (11%) | called by muse, mutect2, varscan2
- TENM3 | c.511+102149G>C | Intron (SNP) | VAF 91/289 reads (31%) | catalogued as COSV101304949; called by muse, mutect2, varscan2
- TIE1 | c.373+16G>T | Intron (SNP) | VAF 114/321 reads (36%) | called by muse, mutect2, varscan2
- TSTD2 | chr9:97633797 C>T | 5'Flank (SNP) | VAF 27/111 reads (24%) | catalogued as rs756524841; called by muse, mutect2, varscan2
- UPK3A | c.-11C>T | 5'UTR (SNP) | VAF 114/211 reads (54%) | called by muse, mutect2, varscan2
- USP10 | c.-52G>T | 5'UTR (SNP) | VAF 64/297 reads (22%) | called by muse, mutect2, varscan2
- VPS11 | c.-892C>A | 5'UTR (SNP) | VAF 102/495 reads (21%) | called by muse, mutect2, varscan2
- WDR1 | c.17-42C>T | Intron (SNP) | VAF 16/136 reads (12%) | catalogued as rs767552022; called by muse, mutect2
- WDR11 | c.-39G>T | 5'UTR (SNP) | VAF 40/412 reads (10%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5332C>A | Intron (SNP) | VAF 69/408 reads (17%) | called by muse, mutect2, varscan2
- ZNF10 | c.33+406A>G | Intron (SNP) | VAF 8/106 reads (8%) | catalogued as rs1434539912; called by muse, mutect2
- ZNF208 | c.*464C>A | 3'UTR (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
- ZNF575 | c.-29G>C | 5'UTR (SNP) | VAF 37/376 reads (10%) | called by muse, mutect2
- ZNF846 | c.15+38T>C | Intron (SNP) | VAF 130/220 reads (59%) | called by muse, mutect2, varscan2
